Somatic mutation profile of tumor specimen TCGA-GV-A3QG-01A (aliquot TCGA-GV-A3QG-01A-11D-A21Z-08) from TCGA case TCGA-GV-A3QG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.3 years (23,847 days).
Specimen TCGA-GV-A3QG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32e812ca-9558-4278-be12-0637d3720470.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3QG-10A (Blood Derived Normal), aliquot TCGA-GV-A3QG-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e5ee816-6745-4ff1-9339-b74b8758b8ad

The open-access MAF lists 90 somatic variants for this specimen: 69 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Nonsense Mutation 4, Frame Shift Ins 3, RNA 2, 3'UTR 1, Splice Site 1, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs779987458, CM053206, COSV50280819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV66859587; called by mutect2, varscan2
- ADK | c.746G>C p.R249T (on ENST00000286621; = p.R232T on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV54205836; called by muse, mutect2, varscan2
- ANK2 | c.11032+2T>G p.X3678_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | catalogued as COSV52160565; called by muse, mutect2, varscan2
- ARHGAP32 | c.5905G>C p.E1969Q (on ENST00000310343 / NM_001378025.1; = p.E1620Q on NM_014715.4) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.074); catalogued as rs1044615421, COSV59847550; called by muse, mutect2, varscan2
- ATM | c.6280G>A p.E2094K | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV53735843; called by muse, mutect2, varscan2
- CATSPERD | c.177C>A p.C59* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as rs768213227, COSV67537332; called by muse, mutect2, varscan2
- CBLL2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs780904588, COSV60369007; called by muse, mutect2, varscan2
- CCDC60 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV59543736; called by muse, mutect2, varscan2
- CEP57L1 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs753907871, COSV61245274; called by muse, mutect2, varscan2
- CNTNAP2 | c.1114T>A p.Y372N | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62147656; called by muse, mutect2, varscan2
- CREBBP | c.3427G>C p.D1143H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV52123432; called by muse, mutect2, varscan2
- CTSW | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57172326; called by muse, mutect2, varscan2
- CYTL1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.922); catalogued as rs200085707, COSV57036803; called by muse, mutect2, varscan2
- DEFA5 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57962123; called by muse, mutect2
- DEPDC5 | c.2470G>A p.V824I (on ENST00000400246; = p.V893I on NM_014662.5) | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.442); catalogued as rs374944205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.5225A>G p.N1742S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV58619718; called by muse, mutect2, varscan2
- DSG2 | c.2969G>C p.R990T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV55199113; called by muse, mutect2, varscan2
- EFHB | c.1321A>G p.S441G | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV55547982; called by muse, mutect2, varscan2
- ENO1 | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as rs759744149, COSV52303776; called by muse, mutect2, varscan2
- FAT3 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53108708; called by muse, mutect2, varscan2
- GOLGA5 | c.1750C>A p.Q584K | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV50832977; called by muse, mutect2, varscan2
- H2AC6 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV58416046; called by muse, mutect2, varscan2
- HEPHL1 | c.3185C>T p.T1062I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.585); catalogued as COSV59891866; called by muse, mutect2
- HMCN1 | c.4351C>G p.P1451A | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV54884261, COSV54899630; called by muse, mutect2
- HSPA5 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52335350; called by muse, mutect2, varscan2
- IREB2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV104386056, COSV51922455; called by muse, mutect2, varscan2
- ITCH | c.893C>A p.S298Y (on ENST00000262650 / NM_001257137.3; = p.S257Y on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV52931825; called by muse, mutect2, varscan2
- LCN15 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1327583542, COSV60210084; called by muse, mutect2, varscan2
- LHFPL4 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs556836255, COSV55002165; called by muse, mutect2, varscan2
- LRP2 | c.4030G>C p.E1344Q | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55552672; called by muse, mutect2, varscan2
- LRRC66 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58633704; called by muse, mutect2, varscan2
- MALT1 | c.2390A>G p.H797R | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.006); catalogued as COSV61934861; called by muse, mutect2, varscan2
- METAP1D | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV59930150; called by muse, mutect2, varscan2
- MORC1 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51719737; called by muse, mutect2, varscan2
- MROH8 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs1410528537; called by muse, mutect2
- MSGN1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as rs373718422; called by muse, mutect2
- NALCN | c.1043C>G p.T348S | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as COSV51934907; called by muse, varscan2
- NCOR2 | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100657344; called by muse, mutect2, varscan2
- NIN | c.5465T>C p.I1822T (on ENST00000382041 / NM_182946.1; = p.I1109T on NM_016350.4) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs745595082, COSV55389844; called by muse, mutect2, varscan2
- NUP107 | c.1701A>C p.E567D | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV57494706; called by muse, mutect2, varscan2
- NXPH2 | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1558909739, COSV55642637; called by muse, mutect2, varscan2
- OR5I1 | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56886891; called by muse, mutect2, varscan2
- PCDHGA2 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as COSV53945637; called by muse, mutect2
- PCDHGB2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53945646; called by muse, mutect2, varscan2
- PDS5B | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV59726965; called by muse, mutect2, varscan2
- PIK3C3 | c.1526G>A p.R509K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV56279217; called by muse, mutect2
- PLCH1 | c.2503G>T p.G835C (on ENST00000340059 / NM_001130960.2; = p.G847C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58196867; called by muse, mutect2, varscan2
- PLEKHH2 | c.2332A>T p.T778S | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV56753556; called by muse, mutect2, varscan2
- PRMT7 | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs781733373, COSV59833363; called by muse, varscan2
- PRRC2C | c.3557G>T p.G1186V (on ENST00000367742; = p.G1184V on NM_015172.4) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV58905199; called by muse, mutect2, varscan2
- SCIN | c.1540C>G p.Q514E (on ENST00000297029 / NM_001112706.3; = p.Q267E on NM_033128.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1221857996, COSV51692508; called by muse, mutect2
- SHROOM3 | c.5780T>C p.M1927T | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV56028895; called by muse, mutect2, varscan2
- SIX4 | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as rs1012956373, COSV53669533; called by muse, mutect2, varscan2
- SORCS3 | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63810079; called by muse, mutect2, varscan2
- SPIRE2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344216110, COSV65555704; called by muse, mutect2, varscan2
- TENM3 | c.2737C>G p.L913V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.332); catalogued as COSV69307662; called by mutect2, varscan2
- THBS2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1220879000, COSV64678786, COSV64680206; called by muse, mutect2, varscan2
- TLN2 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as rs771261514, COSV60887540; called by muse, mutect2, varscan2
- TTN | c.9946G>A p.D3316N (on ENST00000591111; = p.D3270N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/193 reads (8%) | PolyPhen probably damaging (0.951); catalogued as COSV60050869; called by muse, mutect2
- UTP20 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55376885; called by muse, mutect2, varscan2
- XRCC5 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV67536183, COSV67536792; called by muse, mutect2, varscan2
- ADNP2 | c.436_450delinsT p.K146* | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by pindel, varscan2*
- CENPF | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- GLI3 | c.368dup p.H123Qfs*16 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | called by mutect2, pindel
- NFE2L3 | c.1268dup p.L423Ffs*7 | Frame Shift Ins (INS) | VAF 69/199 reads (35%) | called by mutect2, pindel, varscan2
- SNX13 | c.937_939del p.E313del | In Frame Del (DEL) | VAF 8/80 reads (10%) | called by pindel, varscan2
- TET1 | c.5169dup p.G1724Rfs*46 | Frame Shift Ins (INS) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- USP34 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- AFF3 | c.2271A>G p.L757= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV57854117; called by muse, mutect2, varscan2
- AP002748.5 | c.1536G>A p.L512= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV59148594; called by muse, mutect2, varscan2
- DPH1 | c.336G>T p.V112= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV53984593; called by muse, mutect2, varscan2
- ENTHD1 | c.936C>T p.L312= | Silent (SNP) | VAF 48/195 reads (25%) | catalogued as COSV57317319, COSV57320139; called by muse, mutect2, varscan2
- FAM8A1 | c.399C>T p.S133= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV52581429; called by muse, varscan2
- FRMPD4 | c.3465C>T p.T1155= | Silent (SNP) | VAF 66/123 reads (54%) | catalogued as rs373725511, COSV66214737; called by muse, mutect2, varscan2
- GIPR | c.876C>G p.V292= | Silent (SNP) | VAF 76/392 reads (19%) | catalogued as COSV54423949; called by muse, mutect2, varscan2
- HDGFL3 | c.48C>T p.F16= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- HSD17B14 | c.546C>T p.I182= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs763387375, COSV54413418; called by muse, mutect2, varscan2
- LYZL2 | c.303C>T p.S101= (on ENST00000375318; = p.S55= on NM_183058.3) | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs757127551, COSV64684295; called by muse, mutect2, varscan2
- MLIP | c.483C>A p.P161= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV51429762; called by muse, mutect2, varscan2
- OR2B11 | c.576G>A p.S192= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs367979713; called by muse, mutect2, varscan2
- PLAT | c.384C>T p.Y128= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs114679748, COSV54275560; called by muse, mutect2, varscan2
- SATB1 | c.1356G>A p.L452= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV58669340, COSV58669395, COSV58673160; called by muse, mutect2
- SLC12A3 | c.1992C>G p.T664= | Silent (SNP) | VAF 15/145 reads (10%) | catalogued as CD166529, COSV52634863; called by muse, mutect2, varscan2
- SMTN | c.915C>T p.P305= | Silent (SNP) | VAF 84/289 reads (29%) | catalogued as COSV60777970; called by muse, mutect2, varscan2
- WAC | c.1902G>A p.K634= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV61567601; called by muse, mutect2, varscan2
- DCHS2 | n.5142C>T | RNA (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100601436; called by muse, mutect2, varscan2
- SSPOP | n.14377C>T | RNA (SNP) | VAF 82/247 reads (33%) | catalogued as COSV65129854; called by muse, mutect2, varscan2
- USH1C | c.1284+1156G>A | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs925753926, COSV50017442, COSV50020380; called by muse, mutect2, varscan2
- XIRP2 | c.*128G>A | 3'UTR (SNP) | VAF 14/65 reads (22%) | catalogued as rs759247920, COSV54699441; called by muse, mutect2, varscan2
